Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3496, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3496-01A (Primary Tumor).

Diagnosis / Diagnoses:

1.: Right hemicolectomy specimen, under inclusion of a centrally ulcerated, moderately differentiated adenocarcinoma of the colorectal type and of a maximum of 3 cm in length, with infiltration of the pericolic fat tissue. No regional lymph node metastases.

Tumor-free resection margins and tumor-free omental fat tissue.

2.: Moderate chronic fibrosing cholecystitis with chronic fibrosing pericholecystitis and cholecystolithiasis.

Tumor stage: pT3 pN0 (0/23) pMX; G2

Source: NCI Genomic Data Commons file 1affd6fe-2774-4de3-b1b5-935e11117399 (TCGA-AA-3496.0160BBA3-9274-4457-BF4A-CA77C8F050B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).